CCDI case PBBKBP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/50976b51-8470-4720-a50b-13312687f975

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 3.7 years (1,344 days).

Biospecimens (3 samples)
- Sample 0DAXP1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DAXP6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAXP8: Tissue type: Tumor; Specimen type: Solid Tissue.
